Gene-level copy-number profile of tumor specimen TCGA-DA-A1IA-06A from TCGA case TCGA-DA-A1IA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.2 years (13,599 days).
Specimen TCGA-DA-A1IA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.35d22115-1e65-4db5-bdd2-22c188605b85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A1IA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b136995-3261-49ef-ba23-324e2575c100

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 8,211; copy number 3: 31,469; copy number 4: 16,133; copy number 5: 1,299; copy number 6: 1,608; copy number 7: 22; copy number 8: 40; copy number 9: 11; copy number 10: 61; copy number 11: 145; copy number 12: 6; copy number 13: 77; copy number 15: 157; copy number 16: 538; copy number 19: 27; copy number 22: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A1IA-06A-11D-A194-01): tumor purity 0.94, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,088 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,198,212–74,766,678, 11 genes, copy number 9: FPGT, FPGT-TNNI3K, TNNI3K, AC093158.1, AC105271.1, LRRC53, ERICH3, ERICH3-AS1, AC135803.1, CRYZ, TYW3.
- chr1:75,202,131–78,138,444, 51 genes, copy number 7–22 (within-gene range 3–22): SLC44A5, AC093156.1, RNU6-503P, AL096829.1, AL137803.1, ACADM, DLSTP1, RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4, ASB17, AC092813.1, AC092813.2, ST6GALNAC3, AC103592.1, AC104458.1, TPI1P1, RNU6-161P, LINC02567, ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1, AC093433.1, AC093433.2, AK5, AC095030.1, RNU7-8P, AC093575.1, ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2.
- chr1:78,303,884–78,540,701, 1 gene, copy number 8 (within-gene range 3–8): PTGFR.
- chr1:78,619,922–78,666,695, 3 genes, copy number 8: IFI44L, IFI44, AC104837.2.
- chr1:143,343,180–170,116,576, 1,018 genes, copy number 8–19 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 8 (within-gene range 3–8): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
